Somatic mutation profile of tumor specimen MP2PRT-PASPLI-TMP1-A (aliquot MP2PRT-PASPLI-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPLI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,159 days).
Specimen MP2PRT-PASPLI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5a9620f-a356-4aee-9b67-0e5d7dffabf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPLI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPLI-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/345ce476-8ceb-4555-93a3-2cc77f4d1f07

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCND3 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 50/570 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1557768261, COSV56179593; ClinVar: uncertain significance; called by muse, mutect2
- LINGO1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 181/475 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs758902124; called by muse, mutect2, varscan2
- SLC5A1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs370932142, COSV56685019; called by muse, varscan2
- TTLL5 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768300225, COSV104405547; called by muse, mutect2
- ARID1A | c.1113dup p.Q372Afs*28 | Frame Shift Ins (INS) | VAF 184/629 reads (29%) | called by mutect2, pindel, varscan2
- CDH23 | c.4909C>T p.P1637S | Missense Mutation (SNP) | VAF 175/431 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EP300 | c.5281dup p.M1761Nfs*122 | Frame Shift Ins (INS) | VAF 48/438 reads (11%) | called by pindel, varscan2
- NPM2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2
- POU2AF1 | c.491dup p.L165Afs*78 | Frame Shift Ins (INS) | VAF 188/529 reads (36%) | called by mutect2, pindel, varscan2
- SERPINF1 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 165/423 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TOPAZ1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 160/472 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.33); called by muse, varscan2
- FAM110B | c.123C>T p.A41= | Silent (SNP) | VAF 195/546 reads (36%) | called by muse, mutect2, varscan2
- H4C5 | c.271C>T p.L91= | Silent (SNP) | VAF 135/338 reads (40%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+127C>A | Intron (SNP) | VAF 118/505 reads (23%) | called by muse, mutect2, varscan2
